TCGA case TCGA-D7-A748 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bf0f1735-f94d-4b82-8f91-2fd2bac80e32

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 41 years; Vital status: Dead; Days to death: 132 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Carcinoma, diffuse type (the primary disease): ICD-O-3 morphology code: 8145/3; ICD-10 code: C16.1; Tissue or organ of origin: Fundus of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 41.6 years (15,190 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N3; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 12; Lymph nodes tested: 16.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 40 days; Days to treatment end: 72 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 42 days; Days to treatment end: 104 days; Treatment dose: 34 Gy; Treatment outcome: Progressive Disease; Number of fractions: 2; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Epirubicin + Oxaliplatin; Days to treatment start: 104 days; Days to treatment end: 104 days; Treatment outcome: Progressive Disease.
2. Metastasis of diagnosis 1 (Carcinoma, diffuse type), site: Peritoneum, NOS. Age at diagnosis: 41.9 years (15,289 days); Days to diagnosis: 99 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 99 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Peritoneum, NOS; Days to progression: 99 days; Evidence of progression type: Convincing Image Source.
- Day 99 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 99 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 132 days; Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D7-A748-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 320 mg.
  Slide TCGA-D7-A748-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-D7-A748-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D7-A748-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Diffuse Type; Cause of death: Stomach Cancer; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Tumor sample procurement country: wlkp; Cancer procurement city: poznan.
- Drug treatment 1: Pharmaceutical therapy drug name: epirubicinum; Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-FU; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: Oxaliplatinum; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Pharmaceutical therapy drug name: Capecytabinum; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form: Lost to follow-up: No; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Cause of death: Stomach Cancer.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form, New neoplasm event types: New tumor event type: Locoregional Recurrence; New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 132 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 132 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 99 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D7-A748-01A-12D-A32M-01): tumor purity 0.15, ploidy 2.08, whole-genome doublings 0.
